Surgical pathology report (de-identified scan), TCGA case TCGA-BR-A44T, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-A44T-01A (Primary Tumor).

Procurement Date: Laterality: Adenocarcinoma of the stomach, diffuse type, G-3, with invasion into the subserosa. Ten examined lymph nodes form the greater and lesser curvatures demonstrated reactive hyperplasia, lipomatosis. Omentum is of normal structure.

Path Report: STOMACH TISSUE CHECKLIST

Specimen type: Subtotal gastrectomy

Tumor site: Cardia

Tumor size: 0 x 0 x 6 cm

Tumor features: Ulcerated

Histologic type: Adenocarcinoma, diffuse type

Histologic grade: Poorly differentiated

Tumor extent: Subserosa

Lymph nodes: 0/10 positive for metastasis (Greater and lesser curvature 0/10)

Lymphatic invasion: Not specified

Venous invasion: Absent

Perineural invasion: Not specified

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

ICD-O-3

adenocarcinoma, diffuse type

8145/3

Site: stomach, cardia, NOS

8/31/12
RD

C16.0

Signature: [Handwritten Signature] Date: 8/31/12

Source: NCI Genomic Data Commons file 40d5829f-ff98-49c4-b652-fd7c72e34727 (TCGA-BR-A44T.6C1D6C98-3D06-4946-86B0-BD86960103B8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).